Somatic mutation profile of tumor specimen TCGA-HT-A74O-01A (aliquot TCGA-HT-A74O-01A-11D-A32B-08) from TCGA case TCGA-HT-A74O, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 34.1 years (12,460 days).
Specimen TCGA-HT-A74O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c96b6a17-3c3a-4f76-9563-d06af0de86fb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-A74O-10A (Blood Derived Normal), aliquot TCGA-HT-A74O-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/26fd56ba-6506-40a5-bfd0-e6a484bdc11c

The open-access MAF lists 20 somatic variants for this specimen: 15 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 12, Silent 5, In Frame Del 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>G p.R132G | Missense Mutation (SNP) | VAF 21/44 reads (48%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.883); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.381_383del p.P128del | In Frame Del (DEL) | VAF 16/28 reads (57%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- GLIPR1L1 | c.654G>C p.K218N (on ENST00000378695 / NM_001304964.2; = p.K209N on NM_152779.4) | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV100157213; called by muse, mutect2, varscan2
- HIVEP3 | c.1919G>T p.G640V | Missense Mutation (SNP) | VAF 8/139 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV99911134; called by muse, mutect2
- LLGL2 | c.2282G>A p.R761Q | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.042); catalogued as rs749218398, COSV51399111; called by muse, mutect2, varscan2
- MFSD14B | c.177G>T p.W59C | Missense Mutation (SNP) | VAF 46/154 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100942549; called by muse, mutect2, varscan2
- MUC16 | c.29940G>T p.L9980F | Missense Mutation (SNP) | VAF 11/190 reads (6%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.354); catalogued as rs1280540573, COSV101197401, COSV67470663; called by muse, mutect2
- OR8H3 | c.87T>A p.F29L | Missense Mutation (SNP) | VAF 61/174 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as COSV100538682; called by muse, mutect2, varscan2
- PHF20 | c.568C>T p.R190* | Nonsense Mutation (SNP) | VAF 14/91 reads (15%) | catalogued as COSV59186928; called by muse, mutect2, varscan2
- PREX2 | c.2439C>A p.D813E | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.62); catalogued as COSV99904287; called by muse, mutect2
- PTBP1 | c.642C>G p.I214M | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100608246; called by muse, mutect2
- SPIN1 | c.738G>C p.K246N | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101020897; called by muse, mutect2, varscan2
- TTC13 | c.604C>G p.L202V | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.978); catalogued as COSV64170756; called by muse, mutect2
- ZDHHC19 | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56350195; called by muse, mutect2, varscan2
- ATRX | c.5104_5107del p.E1702Yfs*22 | Frame Shift Del (DEL) | VAF 80/107 reads (75%) | called by mutect2, pindel, varscan2
- CACNA2D2 | c.2289C>T p.D763= (on ENST00000479441 / NM_001174051.3; = p.D756= on NM_006030.4) | Silent (SNP) | VAF 14/28 reads (50%) | catalogued as rs375235408; called by muse, mutect2, varscan2
- CPVL | c.111A>G p.G37= | Silent (SNP) | VAF 5/78 reads (6%) | catalogued as COSV99605158; called by muse, mutect2
- KIAA0895L | c.1317C>T p.H439= | Silent (SNP) | VAF 8/112 reads (7%) | catalogued as COSV99220333; called by muse, mutect2
- METAP1D | c.966G>A p.S322= | Silent (SNP) | VAF 12/143 reads (8%) | catalogued as COSV59929823; called by muse, mutect2
- SEMA3C | c.249T>C p.S83= | Silent (SNP) | VAF 28/59 reads (47%) | catalogued as COSV99542178; called by muse, mutect2, varscan2
